Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AACB, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AACB-01A (Primary Tumor).

[page 1 of 3]
ICD O-3

Carcinoma, hepatocellular NOS 8170/3
Site: Liver C22.0
Qx 5/19/14

CLINICAL DIAGNOSIS: HCC

Specimen : Liver

Gross Photo : 1

GROSS:

1. Specimen:

Liver: 16.0 x 13.0 x 6.0 cm, 678.0 gm, unfixed

Gallbladder:

9.5 cm in length, 4.2 cm in diameter, 0.2 cm in wall thickness, unfixed

2. Tumor location: right

Tumor number: one

Tumor size: 4.4 x 4.0 x 3.8 cm

3. Satellite nodule: no

4. Gross type

HCC: expanding nodular

5. Tumor necrosis: yes (10 %)

6. Hemorrhage/peliosis: no

7. Portal vein invasion: no

8. Bile duct invasion: no

Gross photo present.

Blocks

T1-4, tumor of liver x 4

A, non-tumorous parenchymal tissue x 1

RM, resection margin of liver x 1

GB, gallbladder x 1

MICROSCOPIC:

1. Hepatocellular carcinoma: yes

1-1. Differentiation

The worst differentiation III

The major differentiation III

1-2. Histologic type: trabecular

1-3. Cell type: hepatic

1-4. Fatty change: no

2. Cholangiocarcinoma: no

3. Combined hepatocellular and cholangiocarcinoma: no

4. Other tumor: no

5. Fibrous capsule formation: complete capsule

6. Capsular infiltration: no

[page 2 of 3]
- 7. Septum formation: yes
- 8. Surgical resection margin invasion: no, margin of the clearance (0.5 cm)
- 9. Serosal invasion: no
- 10. Portal vein invasion: no
- 11. Bile duct invasion: no
- 12. Hepatic vein invasion: no
- 13. Hepatic artery invasion: no
- 14. Microvessel invasion: yes
- 15. Intrahepatic metastasis: no
- 16. Multicentric occurrence: no

Non-tumor liver pathology

- 1. Chronic hepatitis: yes
- 1-1. Etiology: HBV
- 1-2. Grade, lobular: minimal
- 1-3. Grade, portoperiportal: mild
- 1-4. Stage (fibrosis): cirrhosis
- 1-5. Cirrhosis: macronodular
- 2. Dysplastic nodule: no
- 3. Ductal epithelial dysplasia: no
- 4. Other liver diseases: no

SPECIAL STAIN: Trichrome (+)

knee Joint, replacement, degenerative arthritis

Stomach, antrum, scopic, Hyperplastic polyp

Liver, ectomy, hepatocellular carcinoma, cirrhosis,
T56000, P10, M81703, M49500
Gallbladder, ectomy, chronic cholecystitis
T57000, P10, M43005

DIAGNOSIS:

Liver, right, lobectomy:
Hepatocellular carcinoma, moderately differentiated
Cirrhosis, macronodular
Gallbladder, cholecystectomy:
Chronic cholecystitis

NOTE: Recommend to order immunohistochemistry (CK7, hepatocyte, CK19).

[page 3 of 3]
Suggestion :

Source: NCI Genomic Data Commons file 3e227368-e678-463e-952e-b5157684726c (TCGA-DD-AACB.40E83F82-43B5-426D-A120-2F2F597332C6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).